FM case AD520 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Other and unspecified urinary organs.
https://portal.gdc.cancer.gov/cases/c785bbfe-3ffa-496b-85bd-a23e586afe1f

Female, 70.2 years: Urothelial carcinoma, NOS (ICD-O-3 8120/3) of the urethra; metastasis biopsied or resected from the abdomen. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
